Somatic mutation profile of tumor specimen TCGA-D9-A4Z5-01A (aliquot TCGA-D9-A4Z5-01A-11D-A25O-08) from TCGA case TCGA-D9-A4Z5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.4 years (24,979 days).
Specimen TCGA-D9-A4Z5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3b6b125-6d8e-4a61-be5b-83843f9c8d3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A4Z5-10A (Blood Derived Normal), aliquot TCGA-D9-A4Z5-10A-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ba950fd-db49-4af8-9e7f-c0bb11cdedbe

The open-access MAF lists 72 somatic variants for this specimen: 57 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 14, Nonsense Mutation 3, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1861A>C p.N621H (on ENST00000288602 / NM_001374244.1; = p.N581H on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs180177040, CM060878, COSV56062673, COSV56077649, COSV56286119; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1270G>T p.G424W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56474114; called by muse, mutect2, varscan2
- AGO2 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV55045304; called by muse, mutect2, varscan2
- ANKMY2 | c.1215G>T p.K405N | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV61011017; called by muse, mutect2
- ARID5A | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.82); catalogued as rs1338519900, COSV62590753, COSV62591175; called by muse, mutect2
- BAG6 | c.3449G>A p.R1150Q (on ENST00000676571; = p.R1103Q on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs766837426, COSV52988388, COSV52989770; called by muse, mutect2, varscan2
- BCKDHB | c.776C>G p.P259R | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV57509806; called by muse, mutect2, varscan2
- BTNL8 | c.539G>T p.R180M | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV51456941; called by muse, mutect2, varscan2
- CACNA1D | c.3743T>C p.F1248S (on ENST00000350061 / NM_001128840.3; = p.F1268S on NM_000720.4) | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55438382; called by muse, mutect2, varscan2
- CCDC87 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as rs1238397115, COSV59578411; called by muse, mutect2, varscan2
- COL4A1 | c.4132G>A p.G1378S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65421714; called by muse, mutect2, varscan2
- CTSG | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53534478; called by muse, mutect2, varscan2
- CYP2S1 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV59505113; called by muse, mutect2, varscan2
- EML2 | c.859C>G p.Q287E | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV55597677; called by muse, mutect2, varscan2
- FAM161A | c.1790A>G p.E597G | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV68325220; called by muse, mutect2, varscan2
- FBN3 | c.6611T>G p.M2204R | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.785); catalogued as COSV54453998; called by muse, varscan2
- FCGBP | c.9388G>A p.A3130T | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as rs367948062; called by muse, mutect2, varscan2
- FCGBP | c.5785G>A p.A1929T | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as rs1273367609; called by muse, mutect2
- FCRLA | c.578C>T p.P193L (on ENST00000367959; = p.P170L on NM_032738.4) | Missense Mutation (SNP) | VAF 126/239 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV52684499; called by muse, mutect2, varscan2
- FLG | c.1007C>G p.P336R | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.031); catalogued as COSV64236994, COSV64243246; called by muse, mutect2, varscan2
- GLB1L2 | c.1793C>A p.P598Q | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56995230; called by muse, mutect2
- GP2 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56892173; called by muse, mutect2, varscan2
- GRIK3 | c.2287A>T p.K763* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV66135928; called by muse, mutect2, varscan2
- INHBB | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs560571608, COSV54677318; called by muse, mutect2, varscan2
- KCNH6 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.365); catalogued as COSV59000941; called by muse, mutect2, varscan2
- LILRA1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 99/169 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.344); catalogued as COSV52178099; called by muse, mutect2, varscan2
- MAP1LC3C | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV61803506; called by muse, mutect2, varscan2
- MAP3K7 | c.1645G>A p.E549K (on ENST00000369329 / NM_145331.3; = p.E522K on NM_003188.4) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.681); catalogued as COSV65223620, COSV65225338; called by muse, mutect2, varscan2
- MAPRE3 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1230874000, COSV51866285; called by muse, mutect2, varscan2
- MICB | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.994); catalogued as rs766185724, COSV52855463; called by muse, mutect2, varscan2
- MYH4 | c.2323G>A p.G775R | Missense Mutation (SNP) | VAF 258/284 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55112725; called by muse, mutect2, varscan2
- OR1L6 | c.458C>T p.A153V (on ENST00000373684; = p.A117V on NM_001004453.2) | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV59027898; called by muse, mutect2
- OR51A4 | c.364T>C p.F122L | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV66749075; called by muse, mutect2, varscan2
- OR5AC2 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT tolerated (0.3); PolyPhen benign (0.021); catalogued as rs769617683, COSV62279168; called by muse, mutect2, varscan2
- PAF1 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs761456502, COSV55392690; called by muse, mutect2, varscan2
- PFKL | c.1358A>G p.H453R | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as COSV62462671; called by muse, mutect2, varscan2
- PICK1 | c.1210G>T p.G404W | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV57634592; called by muse, mutect2, varscan2
- PRCC | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV54854946, COSV54855609; called by muse, mutect2
- PTPRB | c.3370G>T p.G1124W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV54233152; called by muse, mutect2, varscan2
- PTPRD | c.560C>A p.P187Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.703); catalogued as COSV61929834; called by muse, mutect2, varscan2
- RP1 | c.558C>A p.H186Q | Missense Mutation (SNP) | VAF 71/245 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV55110711, COSV99606961; called by muse, mutect2, varscan2
- RYR1 | c.7679C>T p.P2560L | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1164159550, COSV62089797; called by muse, mutect2, varscan2
- SAAL1 | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV55514538; called by muse, mutect2, varscan2
- SAMD9L | c.4252G>T p.G1418* | Nonsense Mutation (SNP) | VAF 12/118 reads (10%) | catalogued as COSV59079598; called by muse, mutect2, varscan2
- SLC6A11 | c.1045G>T p.G349W | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54390081; called by muse, mutect2, varscan2
- SLC9C2 | c.679G>T p.G227* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV62943992; called by mutect2, varscan2
- SPDEF | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV65000604; called by muse, mutect2, varscan2
- TECPR2 | c.3994G>C p.D1332H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV63969139; called by muse, mutect2, varscan2
- TEKT5 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs986006041, COSV51586663; called by muse, mutect2, varscan2
- TMEM38B | c.218C>A p.P73Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65948966; called by muse, mutect2, varscan2
- TRIP11 | c.2287C>T p.H763Y | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV50913695; called by muse, mutect2, varscan2
- TRPM2 | c.1840C>A p.H614N | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV55966286; called by muse, mutect2, varscan2
- XKR6 | c.1739C>A p.P580Q | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV58654513; called by muse, mutect2
- ZBED2 | c.485G>T p.R162M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as COSV51912951; called by muse, mutect2, varscan2
- ABL2 | c.1909del p.E637Kfs*21 (on ENST00000502732 / NM_007314.4; = p.E622Kfs*21 on NM_005158.5) | Frame Shift Del (DEL) | VAF 60/133 reads (45%) | called by mutect2, pindel, varscan2
- CYP2A7 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.125); called by muse, mutect2
- SEL1L2 | c.2042del p.L681Cfs*29 | Frame Shift Del (DEL) | VAF 26/54 reads (48%) | called by mutect2, pindel, varscan2
- ACE2 | c.2061A>T p.A687= | Silent (SNP) | VAF 60/66 reads (91%) | catalogued as COSV53023851; called by muse, mutect2, varscan2
- ACTRT1 | c.186G>T p.L62= | Silent (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- AKR7A3 | c.315C>T p.P105= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV64389007; called by muse, mutect2, varscan2
- EPHA8 | c.1731G>T p.S577= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV51262969; called by muse, mutect2, varscan2
- KCNJ4 | c.1083G>T p.L361= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV57856202, COSV57857075; called by muse, mutect2
- LDLR | c.2251C>A p.R751= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as CM151414, COSV52941736; called by mutect2, varscan2
- MAGI2 | c.1690C>A p.R564= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV62633901, COSV62635892; called by muse, mutect2, varscan2
- OR10J1 | c.612G>T p.L204= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV71128178; called by muse, mutect2, varscan2
- PARP14 | c.3711G>A p.T1237= | Silent (SNP) | VAF 22/25 reads (88%) | catalogued as rs773729810, COSV71734158; called by muse, mutect2, varscan2
- TMEM190 | c.156C>A p.P52= | Silent (SNP) | VAF 29/185 reads (16%) | catalogued as COSV52581303; called by muse, mutect2, varscan2
- TMTC4 | c.2028C>T p.L676= (on ENST00000376234 / NM_001350577.2; = p.L695= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs148530984; called by muse, mutect2, varscan2
- ZAN | c.7128C>T p.R2376= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV61805408; called by muse, mutect2, varscan2
- ZNF229 | c.1749G>A p.R583= | Silent (SNP) | VAF 34/56 reads (61%) | catalogued as COSV52159860; called by muse, mutect2, varscan2
- ZP2 | c.258G>A p.P86= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs150656642; called by muse, mutect2, varscan2
- TTN | c.10360+1856C>T | Intron (SNP) | VAF 18/72 reads (25%) | catalogued as rs747399267, COSV59875450; called by muse, mutect2, varscan2
